Somatic mutation profile of tumor specimen C3L-02515-03 (aliquot CPT0169040006) from CPTAC case C3L-02515, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 68.6 years (25,050 days).
Specimen C3L-02515-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0395f743-3c7c-411d-8dab-3a3366bf631d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02515-31 (Blood Derived Normal), aliquot CPT0167510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d21ca7e5-7e9a-4de0-9b05-9e0b42238479

The open-access MAF lists 228 somatic variants for this specimen: 154 protein-altering or splice-affecting, 46 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 46, Intron 11, RNA 7, Frame Shift Del 7, Nonsense Mutation 6, Splice Site 6, 3'UTR 4, 5'Flank 3, In Frame Del 3, Splice Region 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2155G>T p.G719C | Missense Mutation (SNP) | VAF 97/449 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28929495, COSV51766606, COSV51767289; ClinVar: pathogenic / drug response / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2303G>T p.S768I | Missense Mutation (SNP) | VAF 50/362 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913465, COSV51768106, COSV51821681, COSV51833841; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 53/298 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTRT1 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.204); catalogued as COSV64419392; called by muse, mutect2, varscan2
- ALKBH7 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 78/413 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as rs974724297; called by muse, mutect2, varscan2
- ANKRD30B | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs865929661; called by muse, mutect2, varscan2
- ASTN1 | c.547C>G p.R183G | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV56070701; called by muse, mutect2
- AXIN1 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51987576, COSV51994894; called by muse, mutect2
- C11orf53 | c.263C>A p.S88Y | Missense Mutation (SNP) | VAF 50/461 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54721470; called by muse, mutect2, varscan2
- CCDC89 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1220393185, COSV57033667; called by muse, mutect2
- CNTN1 | c.136C>A p.Q46K | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV61636232; called by muse, mutect2
- COP1 | c.1747T>C p.Y583H | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1352053056; called by muse, mutect2
- CSMD2 | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs748886122, COSV53917015; called by muse, mutect2, varscan2
- CSMD3 | c.2247G>C p.W749C (on ENST00000297405 / NM_001363185.1; = p.W645C on NM_052900.3) | Missense Mutation (SNP) | VAF 86/240 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99826558; called by muse, mutect2, varscan2
- DVL3 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 29/520 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as rs940208632; called by muse, mutect2
- GIMAP8 | c.1911G>T p.Q637H | Missense Mutation (SNP) | VAF 52/348 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.217); catalogued as COSV100217487; called by muse, mutect2, varscan2
- GLI2 | c.1496G>T p.R499L (on ENST00000361492 / NM_001374353.1; = p.R516L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CM134421, COSV58035089; called by muse, mutect2
- GULP1 | c.55G>C p.A19P | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV100770924; called by muse, mutect2
- HERC2 | c.10004A>G p.H3335R | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as rs1419376745; called by muse, mutect2
- HHLA2 | c.311C>A p.A104E | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63315976; called by muse, mutect2
- HTR3A | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 42/465 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.431); catalogued as COSV55470024; called by muse, mutect2
- KIAA1217 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756871638; called by muse, mutect2, varscan2
- KIF14 | c.1567G>C p.E523Q | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66260274; called by muse, mutect2
- MAP2K3 | c.649G>T p.D217Y (on ENST00000342679 / NM_145109.3; = p.D188Y on NM_002756.4) | Missense Mutation (SNP) | VAF 44/494 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243698443; called by muse, mutect2
- MUC16 | c.17126C>A p.A5709D | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs769213362, COSV67452281; called by muse, mutect2, varscan2
- NOTCH1 | c.4015-1G>T p.X1339_splice | Splice Site (SNP) | VAF 6/110 reads (5%) | catalogued as COSV53034795; called by muse, mutect2
- PCDHA13 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 11/229 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as rs1554175639, COSV56496343; called by muse, mutect2
- PCDHA8 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 70/700 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.909); catalogued as rs1554139783, COSV65323830; called by muse, mutect2
- PCDHB15 | c.1732C>G p.R578G | Missense Mutation (SNP) | VAF 103/795 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs1280052373, COSV51425229; called by muse, mutect2, varscan2
- PHYHIPL | c.969C>A p.H323Q | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs201417661; called by muse, mutect2, varscan2
- PREX1 | c.3492G>T p.M1164I | Missense Mutation (SNP) | VAF 82/356 reads (23%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV100906079; called by muse, mutect2, varscan2
- PRR14L | c.5945A>G p.D1982G | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.553); catalogued as rs976733233; called by muse, mutect2, varscan2
- RTTN | c.5494C>G p.Q1832E | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55345180; called by mutect2, varscan2
- RUFY1 | c.957-2A>G p.X319_splice | Splice Site (SNP) | VAF 28/184 reads (15%) | catalogued as COSV60161437; called by muse, mutect2, varscan2
- SIRPA | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.431); catalogued as rs772964158; called by muse, mutect2
- SLC30A10 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV63073168; called by muse, mutect2, varscan2
- SLC6A6 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100691787; called by muse, mutect2, varscan2
- SORBS2 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 60/558 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV99512128; called by muse, mutect2, varscan2
- SPATA31E1 | c.3937G>T p.A1313S | Missense Mutation (SNP) | VAF 19/298 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.295); catalogued as rs1244571514; called by muse, mutect2
- SPTA1 | c.5941C>T p.Q1981* | Nonsense Mutation (SNP) | VAF 168/570 reads (29%) | catalogued as COSV100934162; called by muse, mutect2, varscan2
- TEX13C | c.1328A>G p.K443R | Missense Mutation (SNP) | VAF 163/727 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.797); catalogued as COSV101188025; called by muse, mutect2, varscan2
- TIGD7 | c.512T>C p.L171P | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.9); catalogued as COSV51915344; called by muse, mutect2
- TNN | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV53429790; called by muse, mutect2
- UGT1A6 | c.242C>G p.P81R | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs747771330; called by muse, mutect2, varscan2
- VSTM2A | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 53/343 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as rs17852553, COSV100173046; called by muse, mutect2, varscan2
- ZIC3 | c.968C>G p.T323R | Missense Mutation (SNP) | VAF 101/413 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM971601, COSV54975789; called by muse, mutect2, varscan2
- ZNF835 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 77/555 reads (14%) | catalogued as rs761562990; called by muse, mutect2, varscan2
- ACTG2 | c.731C>A p.P244Q | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- ACTRT1 | c.88G>T p.G30* | Nonsense Mutation (SNP) | VAF 31/140 reads (22%) | called by muse, mutect2, varscan2
- AK5 | c.1682T>C p.I561T (on ENST00000354567 / NM_174858.3; = p.I535T on NM_012093.4) | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARGFX | c.267G>T p.Q89H | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGAP35 | c.4102_4108delinsC p.N1368_E1370delinsQ | In Frame Del (DEL) | VAF 15/150 reads (10%) | called by pindel, varscan2*
- ARMC9 | c.304A>T p.I102F | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ATG9B | c.237G>T p.Q79H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.892); called by muse, mutect2
- BLMH | c.929A>T p.K310M | Missense Mutation (SNP) | VAF 14/275 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); called by muse, mutect2
- C10orf71 | c.2962G>T p.G988C | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- C17orf80 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 44/327 reads (13%) | called by muse, mutect2, varscan2
- C4orf54 | c.4350G>C p.E1450D | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMK1G | c.1405C>G p.Q469E | Missense Mutation (SNP) | VAF 27/282 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); called by muse, mutect2
- CAMTA1 | c.1091G>T p.S364I | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2
- CASZ1 | c.3676C>A p.Q1226K | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CCDC149 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CEP152 | c.3506del p.G1169Dfs*17 | Frame Shift Del (DEL) | VAF 15/116 reads (13%) | called by mutect2, pindel
- CEP170B | c.3059A>G p.D1020G (on ENST00000453495; = p.D949G on NM_015005.3) | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- CFAP43 | c.3334-1G>T p.X1112_splice | Splice Site (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- CFHR2 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 38/496 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHAF1A | c.1110G>T p.E370D | Missense Mutation (SNP) | VAF 79/373 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CMYA5 | c.1838G>T p.G613V | Missense Mutation (SNP) | VAF 32/325 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CNBP | c.232G>T p.G78C | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CNTN5 | c.2182G>A p.G728R | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A5 | c.4661G>T p.G1554V | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPN2 | c.1327C>A p.L443M | Missense Mutation (SNP) | VAF 39/368 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTTNBP2 | c.1019A>T p.N340I | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CYP2B6 | c.1141A>G p.I381V | Missense Mutation (SNP) | VAF 58/396 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCLK3 | c.1155G>T p.K385N | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCTN2 | c.669del p.V224Sfs*8 (on ENST00000548249 / NM_001261413.2; = p.V229Sfs*8 on NM_006400.4) | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- DKC1 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- DMRTB1 | c.577+8G>T | Splice Region (SNP) | VAF 39/262 reads (15%) | called by muse, mutect2, varscan2
- DNAH9 | c.4490G>T p.G1497V | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2
- DNAH9 | c.8125C>A p.H2709N | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- FAM131B | c.90+3G>C | Splice Region (SNP) | VAF 32/320 reads (10%) | called by muse, mutect2, varscan2
- FLNC | c.1979C>A p.P660H | Missense Mutation (SNP) | VAF 108/447 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- FMR1 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 26/356 reads (7%) | called by muse, mutect2
- FZR1 | c.1358C>G p.P453R | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLG1 | c.2398A>G p.K800E | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- GNPTAB | c.2097del p.N699Kfs*11 | Frame Shift Del (DEL) | VAF 41/262 reads (16%) | called by mutect2, pindel, varscan2
- GPR25 | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GSAP | c.1408+1del p.X470_splice | Splice Site (DEL) | VAF 23/140 reads (16%) | called by mutect2, pindel, varscan2
- H6PD | c.1672G>T p.A558S | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- HAPLN4 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- HECW1 | c.2551G>T p.V851L | Missense Mutation (SNP) | VAF 55/276 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- HGF | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HHIPL1 | c.1316G>A p.W439* | Nonsense Mutation (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- HMMR | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- HS6ST2 | c.1086del p.S363Afs*23 | Frame Shift Del (DEL) | VAF 55/381 reads (14%) | called by mutect2, pindel, varscan2
- HSD17B3 | c.672+1G>T p.X224_splice | Splice Site (SNP) | VAF 64/380 reads (17%) | called by muse, mutect2, varscan2
- ICE1 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.009); called by muse, mutect2
- INSC | c.1031C>A p.A344D | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- IRF2BPL | c.855_860del p.T286_P287del | In Frame Del (DEL) | VAF 7/67 reads (10%) | called by mutect2, pindel
- JAG2 | c.330dup p.A111Cfs*49 | Frame Shift Ins (INS) | VAF 32/285 reads (11%) | called by mutect2, pindel, varscan2
- KCNIP4 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIF4B | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 73/521 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- KLB | c.2182C>G p.R728G | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- KLK4 | c.625G>T p.G209W | Missense Mutation (SNP) | VAF 64/519 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KNDC1 | c.2027A>T p.H676L | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, mutect2
- LCAT | c.1077C>G p.D359E | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- LHFPL1 | c.502del p.A168Pfs*14 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- LIN9 | c.77C>A p.P26Q | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- LRIT1 | c.560C>A p.P187H | Missense Mutation (SNP) | VAF 39/436 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2
- LRRC15 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.241); called by muse, mutect2
- MAP2K7 | c.647A>T p.E216V | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- MCF2 | c.2167C>A p.Q723K | Missense Mutation (SNP) | VAF 92/574 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MEIOC | c.1015C>A p.L339I | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- MMRN2 | c.284T>A p.V95D | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- MSN | c.717del p.F240Sfs*66 | Frame Shift Del (DEL) | VAF 17/134 reads (13%) | called by mutect2, pindel, varscan2
- MTHFD1L | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2
- MTHFSD | c.580G>T p.V194F (on ENST00000360900 / NM_001159377.2; = p.V193F on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MUC4 | c.1465C>A p.P489T | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT tolerated, low confidence (0.58); PolyPhen possibly damaging (0.65); called by muse, mutect2
- MYOM2 | c.2864G>T p.R955M | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2
- MYOM2 | c.3625G>C p.D1209H | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP1 | c.3245C>A p.P1082H | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NOLC1 | c.1962G>T p.W654C | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NRK | c.2203T>C p.F735L | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); called by muse, varscan2
- OR8K1 | c.78C>A p.N26K | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2
- PARP9 | c.2347C>T p.P783S | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- PCDH15 | c.4657_4658del p.S1553Tfs*8 | Frame Shift Del (DEL) | VAF 32/289 reads (11%) | called by mutect2, varscan2
- PCDH7 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHGA2 | c.2077C>A p.L693M | Missense Mutation (SNP) | VAF 42/640 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDGFRA | c.1988C>A p.A663D | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRR23A | c.721G>T p.G241W | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RAB40AL | c.48G>T p.K16N | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBM44 | c.306+2T>A p.X102_splice (on ENST00000611254; = p.X736_splice on NM_001080504.2) | Splice Site (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2
- RBMXL3 | c.2253C>A p.N751K | Missense Mutation (SNP) | VAF 76/360 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- RTL9 | c.3815C>T p.T1272I | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- RYR2 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2
- SALL3 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SLC17A2 | c.379C>A p.L127M | Missense Mutation (SNP) | VAF 100/373 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC26A5 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 19/379 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.474); called by muse, mutect2
- SMOX | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 77/350 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.11588A>C p.Q3863P (on ENST00000367255 / NM_182961.4; = p.Q3848P on NM_033071.3) | Missense Mutation (SNP) | VAF 47/314 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SYNE1 | c.3752G>T p.G1251V (on ENST00000367255 / NM_182961.4; = p.G1258V on NM_033071.3) | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2
- TBL2 | c.1343G>T p.*448Lext*54 | Nonstop Mutation (SNP) | VAF 24/101 reads (24%) | called by muse, mutect2, varscan2
- TEKT4 | c.347C>T p.T116I | Missense Mutation (SNP) | VAF 87/537 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- THNSL2 | c.309G>T p.E103D | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLR4 | c.507G>T p.E169D (on ENST00000355622 / NM_138554.5; = p.E129D on NM_003266.4) | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM154 | c.49_51del p.V17del | In Frame Del (DEL) | VAF 46/424 reads (11%) | called by mutect2, pindel, varscan2
- TPBGL | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- TRIM77 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- TRIM77 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- TTN | c.54665C>T p.A18222V (on ENST00000591111; = p.A10798V on NM_003319.4) | Missense Mutation (SNP) | VAF 14/305 reads (5%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- VPS37A | c.874G>C p.A292P | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- WASHC2A | c.2454G>T p.Q818H | Missense Mutation (SNP) | VAF 30/319 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WIPI1 | c.1058T>C p.L353S | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZNF547 | c.535A>T p.T179S | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- AKAP1 | c.1695G>T p.A565= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV58469134; called by muse, mutect2
- ARHGAP23 | c.174G>T p.L58= | Silent (SNP) | VAF 32/199 reads (16%) | called by muse, mutect2, varscan2
- ATP1A3 | c.1800A>G p.A600= (on ENST00000545399 / NM_001256214.2; = p.A587= on NM_152296.5) | Silent (SNP) | VAF 48/352 reads (14%) | called by muse, mutect2, varscan2
- BCAT1 | c.216T>C p.H72= | Silent (SNP) | VAF 14/352 reads (4%) | catalogued as COSV53914945; called by muse, mutect2
- BCORL1 | c.777T>A p.A259= | Silent (SNP) | VAF 19/224 reads (8%) | called by muse, mutect2
- CACNA2D4 | c.1434C>T p.V478= | Silent (SNP) | VAF 16/183 reads (9%) | called by muse, mutect2
- CDH13 | c.1059C>A p.I353= | Silent (SNP) | VAF 50/304 reads (16%) | called by muse, mutect2, varscan2
- CNGB1 | c.1992G>T p.V664= | Silent (SNP) | VAF 56/480 reads (12%) | catalogued as COSV51897627; called by muse, mutect2, varscan2
- DDX42 | c.1725G>A p.V575= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as COSV100835016; called by muse, mutect2, varscan2
- DENR | c.30G>T p.G10= | Silent (SNP) | VAF 59/386 reads (15%) | called by muse, mutect2, varscan2
- DIDO1 | c.6279G>T p.V2093= | Silent (SNP) | VAF 117/564 reads (21%) | called by muse, mutect2, varscan2
- GABRA4 | c.1447C>T p.L483= | Silent (SNP) | VAF 30/364 reads (8%) | catalogued as rs1182746073; called by muse, mutect2
- GCN1 | c.3849G>T p.T1283= | Silent (SNP) | VAF 28/152 reads (18%) | called by muse, mutect2, varscan2
- GP2 | c.1215C>A p.P405= (on ENST00000381362 / NM_001007240.3; = p.P402= on NM_001502.4) | Silent (SNP) | VAF 8/196 reads (4%) | called by muse, mutect2
- HPSE2 | c.1692G>T p.R564= | Silent (SNP) | VAF 48/314 reads (15%) | catalogued as COSV65187772; called by muse, mutect2, varscan2
- L1CAM | c.2196C>G p.V732= | Silent (SNP) | VAF 46/627 reads (7%) | called by muse, mutect2
- LRRC7 | c.702C>T p.F234= (on ENST00000651989 / NM_001370785.2; = p.F201= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 23/250 reads (9%) | catalogued as rs752776916, COSV50435016; called by muse, mutect2
- MED13L | c.2805G>T p.V935= | Silent (SNP) | VAF 93/545 reads (17%) | called by muse, mutect2, varscan2
- NFKBIZ | c.1497G>T p.L499= | Silent (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- OR2G6 | c.918G>C p.L306= | Silent (SNP) | VAF 38/148 reads (26%) | catalogued as COSV58574152; called by muse, varscan2
- OR2T2 | c.789C>G p.P263= | Silent (SNP) | VAF 130/784 reads (17%) | called by muse, varscan2
- OR2T35 | c.786C>G p.P262= | Silent (SNP) | VAF 73/617 reads (12%) | catalogued as rs1020970216; called by muse, mutect2
- OR4A5 | c.720C>A p.G240= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV60521979; called by muse, mutect2, varscan2
- PCDHB8 | c.489A>T p.I163= | Silent (SNP) | VAF 50/866 reads (6%) | called by muse, mutect2
- PCNX2 | c.2880C>T p.F960= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as COSV50785686; called by muse, mutect2, varscan2
- PNMA8A | c.786C>A p.G262= | Silent (SNP) | VAF 40/323 reads (12%) | called by muse, mutect2, varscan2
- PNPLA6 | c.2028C>T p.S676= (on ENST00000414982 / NM_001166111.2; = p.S628= on NM_006702.5) | Silent (SNP) | VAF 24/468 reads (5%) | called by muse, mutect2
- PRG4 | c.1860C>T p.T620= | Silent (SNP) | VAF 82/234 reads (35%) | catalogued as rs868730735, COSV63355891; called by muse, mutect2, varscan2
- PRKD3 | c.183A>G p.S61= | Silent (SNP) | VAF 42/364 reads (12%) | called by muse, mutect2, varscan2
- PRR23A | c.720G>T p.V240= | Silent (SNP) | VAF 18/154 reads (12%) | called by muse, mutect2, varscan2
- RET | c.1182C>T p.N394= | Silent (SNP) | VAF 40/306 reads (13%) | catalogued as rs376465385, CM000032; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR2 | c.6336C>A p.S2112= | Silent (SNP) | VAF 40/350 reads (11%) | called by muse, mutect2, varscan2
- SLC17A1 | c.492C>A p.P164= | Silent (SNP) | VAF 71/244 reads (29%) | called by muse, mutect2, varscan2
- SLC17A9 | c.813C>T p.P271= | Silent (SNP) | VAF 66/359 reads (18%) | catalogued as rs775071698, COSV100947694; called by muse, mutect2, varscan2
- SLC1A3 | c.27C>T p.P9= | Silent (SNP) | VAF 21/168 reads (13%) | called by muse, mutect2, varscan2
- SLC22A11 | c.492C>A p.S164= | Silent (SNP) | VAF 17/137 reads (12%) | called by muse, mutect2, varscan2
- SLC2A7 | c.570C>A p.A190= | Silent (SNP) | VAF 21/184 reads (11%) | called by muse, mutect2, varscan2
- SMIM23 | c.375G>T p.L125= | Silent (SNP) | VAF 60/370 reads (16%) | called by muse, mutect2, varscan2
- SP3 | c.1263C>A p.I421= | Silent (SNP) | VAF 56/468 reads (12%) | called by muse, mutect2, varscan2
- TMBIM4 | c.225G>A p.L75= | Silent (SNP) | VAF 9/216 reads (4%) | called by muse, mutect2
- TPH2 | c.1263T>A p.V421= | Silent (SNP) | VAF 21/409 reads (5%) | called by muse, mutect2
- TRPS1 | c.3225G>T p.A1075= (on ENST00000220888 / NM_001330599.2; = p.A1088= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 101/645 reads (16%) | catalogued as COSV55254779; called by muse, mutect2, varscan2
- UFSP2 | c.1101G>A p.T367= | Silent (SNP) | VAF 13/159 reads (8%) | catalogued as rs755002032, COSV52990961; called by muse, mutect2
- UNC45A | c.2046C>T p.G682= | Silent (SNP) | VAF 18/186 reads (10%) | called by muse, mutect2, varscan2
- WDR77 | c.249G>C p.V83= | Silent (SNP) | VAF 79/399 reads (20%) | called by muse, mutect2, varscan2
- ZNF783 | c.183G>T p.L61= | Silent (SNP) | VAF 38/314 reads (12%) | called by muse, mutect2, varscan2
- AC004890.2 | n.2191A>T | RNA (SNP) | VAF 41/387 reads (11%) | called by muse, mutect2, varscan2
- AC090155.1 | n.351C>A | RNA (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- ACE | c.*206A>T | 3'UTR (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- ALDH1L1 | chr3:126181003 G>A | 5'Flank (SNP) | VAF 14/225 reads (6%) | called by muse, mutect2
- AP003393.1 | n.846C>A | RNA (SNP) | VAF 124/478 reads (26%) | called by muse, mutect2, varscan2
- BMS1P22 | chr22:15820646 G>T | 5'Flank (SNP) | VAF 14/66 reads (21%) | called by mutect2, varscan2
- C5orf60 | n.2363C>A | RNA (SNP) | VAF 64/728 reads (9%) | called by muse, mutect2
- CHRNA4 | c.1759-32C>A | Intron (SNP) | VAF 119/627 reads (19%) | called by muse, mutect2, varscan2
- DCN | c.885+20T>A | Intron (SNP) | VAF 51/269 reads (19%) | called by muse, mutect2, varscan2
- DNMT3A | c.-178+13764G>T | Intron (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- EPDR1 | c.-189_-174del | 5'UTR (DEL) | VAF 24/250 reads (10%) | called by mutect2, pindel
- FAM184A | c.159+9040G>T | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- FBLN7 | c.-10G>T | 5'UTR (SNP) | VAF 47/469 reads (10%) | called by muse, mutect2
- FLT4 | c.2647+140C>T | Intron (SNP) | VAF 26/355 reads (7%) | called by muse, mutect2
- FOXP2 | c.*181T>A | 3'UTR (SNP) | VAF 39/265 reads (15%) | called by muse, mutect2, varscan2
- FSD2 | c.*3376T>C | 3'UTR (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- GET1 | c.336+38G>T | Intron (SNP) | VAF 33/174 reads (19%) | called by muse, mutect2, varscan2
- GUSBP10 | n.246G>T | RNA (SNP) | VAF 81/370 reads (22%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.396C>A | RNA (SNP) | VAF 75/480 reads (16%) | called by muse, mutect2, varscan2
- PDE6A | c.1473+28C>A | Intron (SNP) | VAF 94/428 reads (22%) | called by muse, mutect2, varscan2
- PEX14 | c.169+37G>T | Intron (SNP) | VAF 26/215 reads (12%) | called by muse, mutect2, varscan2
- POR | c.237+75G>T | Intron (SNP) | VAF 42/187 reads (22%) | catalogued as rs782026654; called by muse, mutect2, varscan2
- PRDM11 | chr11:45227803 C>T | 3'Flank (SNP) | VAF 30/265 reads (11%) | called by muse, mutect2, varscan2
- PRKCSH | c.1176-26C>T | Intron (SNP) | VAF 10/258 reads (4%) | called by muse, mutect2
- RNA5S17 | chr1:228650413 C>T | 5'Flank (SNP) | VAF 22/620 reads (4%) | called by muse, mutect2
- RNF217-AS1 | n.1429G>T | RNA (SNP) | VAF 13/240 reads (5%) | called by muse, mutect2
- TDP1 | c.1753+27G>C | Intron (SNP) | VAF 47/348 reads (14%) | catalogued as COSV100187860; called by muse, mutect2, varscan2
- ZPBP | c.*43A>G | 3'UTR (SNP) | VAF 36/180 reads (20%) | catalogued as rs762017784; called by mutect2, varscan2
